Somatic mutation profile of tumor specimen C3L-01668-01 (aliquot CPT0186560011) from CPTAC case C3L-01668, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IA; FIGO stage: Stage IA; Tumor grade: G2; Age at diagnosis: 37.3 years (13,619 days).
Specimen C3L-01668-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b3190f62-0d51-45c9-9d72-198b28c33381.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01668-31 (Blood Derived Normal), aliquot CPT0186620002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d30c42fa-386c-4305-b09e-50ca1e692d1f

The open-access MAF lists 65 somatic variants for this specimen: 45 protein-altering or splice-affecting, 15 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 15, Frame Shift Del 5, Intron 2, In Frame Del 2, Nonsense Mutation 2, 3'UTR 2, Frame Shift Ins 1, Splice Region 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1513C>G p.R505G (on ENST00000281708 / NM_001349798.2; = p.R425G on NM_018315.5) | Missense Mutation (SNP) | VAF 70/356 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ING1 | c.1015C>T p.R339* | Nonsense Mutation (SNP) | VAF 32/166 reads (19%) | hotspot (GDC flag); catalogued as COSV58167363; called by muse, mutect2, varscan2
- ABR | c.2284C>T p.R762C (on ENST00000302538 / NM_021962.5; = p.R725C on NM_001092.5) | Missense Mutation (SNP) | VAF 49/249 reads (20%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.93); catalogued as rs1239048419; called by muse, mutect2, varscan2
- ADGRA3 | c.2799G>A p.M933I | Missense Mutation (SNP) | VAF 58/238 reads (24%) | SIFT tolerated (1); PolyPhen possibly damaging (0.6); catalogued as rs1174910166; called by muse, mutect2, varscan2
- ANKRD30B | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV62815462; called by muse, mutect2, varscan2
- CCDC168 | c.12265G>A p.A4089T | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs760630397; called by muse, mutect2, varscan2
- CCND1 | c.817G>T p.E273* | Nonsense Mutation (SNP) | VAF 28/123 reads (23%) | catalogued as COSV57121723; called by muse, mutect2, varscan2
- CPNE6 | c.1541C>T p.A514V | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs764762191; called by muse, mutect2
- CTAGE1 | c.728del p.K243Rfs*2 | Frame Shift Del (DEL) | VAF 47/212 reads (22%) | catalogued as COSV66944196; called by mutect2, pindel, varscan2
- DTNA | c.1511C>T p.T504M | Missense Mutation (SNP) | VAF 74/447 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as rs199828427; called by muse, mutect2, varscan2
- IL1R2 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs570040319, COSV60205918; called by muse, mutect2
- ITIH1 | c.476C>T p.T159M | Missense Mutation (SNP) | VAF 52/287 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.432); catalogued as rs755550027; called by muse, mutect2
- LIME1 | c.689C>T p.A230V | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs746290002; called by muse, mutect2, varscan2
- MED12 | c.4385G>A p.R1462H | Missense Mutation (SNP) | VAF 40/193 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV61335886; called by muse, mutect2, varscan2
- NEXN | c.1112C>T p.P371L | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200067011, COSV57361854; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTEN | c.595_597del p.M199del | In Frame Del (DEL) | VAF 26/160 reads (16%) | catalogued as rs1064793244; called by pindel, varscan2
- PTEN | c.955_958del p.T319* | Frame Shift Del (DEL) | VAF 30/182 reads (16%) | catalogued as rs146650273; called by pindel, varscan2
- RALGPS2 | c.1549G>A p.V517I | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs766175478; called by muse, mutect2, varscan2
- RFC4 | c.882+3A>G | Splice Region (SNP) | VAF 42/221 reads (19%) | catalogued as rs1221538688; called by muse, mutect2, varscan2
- SATB2 | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 88/415 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); catalogued as rs1489038642, COSV53483870; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC28A1 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 82/447 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.302); catalogued as rs759745634; called by muse, mutect2, varscan2
- TENM4 | c.8113C>T p.R2705C | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as rs570712669, COSV53673255; called by muse, mutect2, varscan2
- TMEM41A | c.788A>G p.D263G | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs1157289137; called by muse, mutect2, varscan2
- TTC39A | c.929G>A p.R310Q (on ENST00000447632 / NM_001297665.1; = p.R275Q on NM_001080494.3) | Missense Mutation (SNP) | VAF 103/260 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0.232); catalogued as rs765718230, COSV52957389; called by muse, mutect2, varscan2
- ZNF628 | c.1159C>T p.R387C | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs899314399; called by muse, mutect2, varscan2
- ALDH1B1 | c.1285A>G p.K429E | Missense Mutation (SNP) | VAF 38/203 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- ARID1A | c.2945_2948dup p.N983Kfs*25 | Frame Shift Ins (INS) | VAF 38/119 reads (32%) | called by mutect2, pindel, varscan2
- CDKN1B | c.336_345del p.S112Rfs*4 | Frame Shift Del (DEL) | VAF 34/178 reads (19%) | called by mutect2, pindel, varscan2
- EGF | c.2336C>G p.T779R | Missense Mutation (SNP) | VAF 91/433 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EYS | c.6409C>A p.R2137S | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.396); called by muse, mutect2
- GUCY2D | c.2543_2549del p.K848Tfs*16 | Frame Shift Del (DEL) | VAF 55/321 reads (17%) | called by mutect2, pindel, varscan2
- HLTF | c.2385_2400del p.K796Efs*10 | Frame Shift Del (DEL) | VAF 23/180 reads (13%) | called by mutect2, pindel
- NOTCH1 | c.6905C>T p.T2302I | Missense Mutation (SNP) | VAF 114/610 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- OR5T3 | c.284T>C p.V95A | Missense Mutation (SNP) | VAF 23/246 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.012); called by muse, mutect2
- PDIA3 | c.1222C>T p.H408Y | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PIK3R1 | c.1341_1358del p.K447_Y452del (on ENST00000521381 / NM_181523.3; = p.K177_Y182del on NM_181504.4) | In Frame Del (DEL) | VAF 14/128 reads (11%) | called by mutect2, pindel
- PIK3R1 | c.1985+1G>T p.X662_splice (on ENST00000521381 / NM_181523.3; = p.X392_splice on NM_181504.4) | Splice Site (SNP) | VAF 13/44 reads (30%) | called by muse, mutect2, varscan2
- QSER1 | c.5087A>C p.K1696T (on ENST00000399302; = p.K1825T on NM_001076786.3) | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RYR1 | c.14023G>A p.E4675K | Missense Mutation (SNP) | VAF 71/365 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- RYR2 | c.14200T>C p.Y4734H | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- SYNE1 | c.1147G>A p.A383T (on ENST00000367255 / NM_182961.4; = p.A390T on NM_033071.3) | Missense Mutation (SNP) | VAF 29/172 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- TDRD7 | c.3157G>C p.V1053L | Missense Mutation (SNP) | VAF 82/443 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- TSPYL2 | c.1391C>G p.T464S | Missense Mutation (SNP) | VAF 22/286 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.026); called by muse, mutect2
- ZFHX4 | c.2038G>A p.G680R | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZNF157 | c.557G>T p.G186V | Missense Mutation (SNP) | VAF 36/183 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CYP4F2 | c.1548G>A p.V516= | Silent (SNP) | VAF 29/196 reads (15%) | catalogued as rs1441605299; called by muse, mutect2, varscan2
- DYNC1H1 | c.12654G>A p.T4218= | Silent (SNP) | VAF 85/413 reads (21%) | catalogued as rs747207435, COSV64135876; ClinVar: likely benign; called by muse, mutect2, varscan2
- GATA4 | c.906C>T p.H302= | Silent (SNP) | VAF 114/647 reads (18%) | catalogued as rs201516339; ClinVar: likely benign; called by muse, mutect2, varscan2
- HDAC8 | c.447A>T p.A149= | Silent (SNP) | VAF 15/81 reads (19%) | called by muse, mutect2, varscan2
- KIF1A | c.1560G>A p.R520= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as rs1318367754; ClinVar: likely benign; called by muse, mutect2, varscan2
- MOK | c.1191G>A p.P397= | Silent (SNP) | VAF 34/150 reads (23%) | catalogued as rs545460566, COSV51964423; called by muse, mutect2, varscan2
- MON2 | c.4611T>C p.Y1537= | Silent (SNP) | VAF 12/81 reads (15%) | called by muse, mutect2, varscan2
- OR4K14 | c.438G>T p.V146= | Silent (SNP) | VAF 40/156 reads (26%) | catalogued as COSV59292725; called by muse, mutect2, varscan2
- PCARE | c.531G>A p.P177= | Silent (SNP) | VAF 100/557 reads (18%) | catalogued as rs200914951; called by muse, mutect2, varscan2
- POTEG | c.297C>A p.G99= | Silent (SNP) | VAF 35/863 reads (4%) | catalogued as COSV101612005; called by muse, mutect2
- REM1 | c.414C>T p.A138= | Silent (SNP) | VAF 33/141 reads (23%) | catalogued as rs755483707; called by muse, mutect2, varscan2
- TEX13C | c.2703G>A p.K901= | Silent (SNP) | VAF 64/314 reads (20%) | called by muse, mutect2, varscan2
- YY1AP1 | c.1473A>G p.K491= (on ENST00000295566 / NM_139118.2; = p.K434= on NM_018253.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 72/273 reads (26%) | catalogued as COSV99803335; called by muse, mutect2, varscan2
- ZBTB34 | c.1083G>A p.A361= | Silent (SNP) | VAF 48/287 reads (17%) | catalogued as rs779656491, COSV59860153; called by muse, mutect2, varscan2
- ZNF510 | c.150C>T p.D50= | Silent (SNP) | VAF 14/93 reads (15%) | catalogued as rs757261182; called by muse, mutect2, varscan2
- ANK1 | c.5619+256G>T | Intron (SNP) | VAF 95/385 reads (25%) | called by muse, mutect2, varscan2
- CSMD2 | c.8311+8262G>T | Intron (SNP) | VAF 98/197 reads (50%) | called by muse, mutect2, varscan2
- IRF8 | c.*16G>A | 3'UTR (SNP) | VAF 69/314 reads (22%) | catalogued as rs751125215, COSV51897389; called by muse, mutect2, varscan2
- RNF217-AS1 | n.2033C>T | RNA (SNP) | VAF 6/29 reads (21%) | catalogued as rs1008515761; called by muse, mutect2, varscan2
- SLC47A1 | c.*2G>A | 3'UTR (SNP) | VAF 32/148 reads (22%) | catalogued as rs778204666; called by muse, mutect2
